Somatic mutation profile of tumor specimen MMRF_2476_1_BM_CD138pos (aliquot MMRF_2476_1_BM_CD138pos_T1_KHS5U_L11618) from MMRF case MMRF_2476, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.1 years (30,355 days).
Specimen MMRF_2476_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 242b87b1-bf7c-4c1a-bed2-bb077e5ccd00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2476_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2476_1_PB_Whole_C3_KHS5U_L11619; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78990820-fb92-45c8-9a8b-5a7d97351f4c

The open-access MAF lists 141 somatic variants for this specimen: 57 protein-altering or splice-affecting, 16 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 33, Silent 16, Intron 16, 5'UTR 8, RNA 6, Nonsense Mutation 4, 3'Flank 3, 5'Flank 2, Splice Site 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 249/437 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 30/148 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2, varscan2
- ACTL9 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61005154; called by muse, mutect2, varscan2
- ARHGEF10 | c.3297G>A p.E1099= (on ENST00000398564; = p.E1074= on NM_014629.4) | Splice Region (SNP) | VAF 58/131 reads (44%) | catalogued as COSV50701126; called by muse, mutect2, varscan2
- ARSA | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs1283017790; called by muse, mutect2, varscan2
- CLEC2L | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); catalogued as rs1367395117, COSV70691219; called by muse, mutect2, varscan2
- FKBP6 | c.561C>G p.F187L | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV52721308; called by muse, mutect2, varscan2
- FRAS1 | c.1832C>A p.S611* | Nonsense Mutation (SNP) | VAF 9/181 reads (5%) | catalogued as COSV53632380; called by muse, mutect2
- GJB5 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 52/407 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs139327105, COSV58356565; called by muse, mutect2, varscan2
- IGHV2-70 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 54/56 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs368831727; called by muse, varscan2
- IGKV4-1 | c.171C>A p.N57K | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs375642722; called by muse, mutect2, varscan2
- IGKV4-1 | c.172T>A p.Y58N | Missense Mutation (SNP) | VAF 63/63 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs7606636; called by muse, mutect2, varscan2
- IGLL5 | c.124A>C p.M42L | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs550903741, COSV73251065, COSV73251253; called by muse, varscan2
- IGLV3-1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as rs371113616; called by muse, mutect2
- LRRK1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV52629021; called by muse, mutect2, varscan2
- NWD2 | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1266803458; called by muse, mutect2, varscan2
- PGD | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.972); catalogued as COSV99581259; called by muse, mutect2, varscan2
- POLR3B | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 132/299 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV57282813; called by muse, mutect2, varscan2
- PRC1 | c.394T>C p.C132R | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs775603430; called by muse, mutect2, varscan2
- RTN4R | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 88/159 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs755593893; called by muse, mutect2, varscan2
- SEMA3E | c.48A>T p.L16F | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57101338; called by muse, mutect2, varscan2
- TCF19 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs368441156; called by muse, mutect2, varscan2
- TPH2 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1435928815; called by muse, mutect2, varscan2
- UBR1 | c.4417G>A p.A1473T | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs139296068; called by muse, mutect2, varscan2
- USP30 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 141/290 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1413811231, COSV57448941; called by muse, mutect2, varscan2
- ZNF142 | c.4904A>G p.H1635R (on ENST00000411696 / NM_001379660.1; = p.H1435R on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs772191289; called by muse, mutect2, varscan2
- ZNF77 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1255091036, COSV58822490; called by muse, mutect2, varscan2
- ABCG8 | c.875T>G p.I292S | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- ABRA | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 123/245 reads (50%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK9 | c.3626_3633+13delinsAGGAGGGAGGTAAGTAGTTT p.X1209_splice | Splice Site (DEL) | VAF 15/97 reads (15%) | called by mutect2*, pindel, varscan2*
- B4GALT6 | c.968A>G p.H323R | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BTG1 | c.125A>G p.Q42R | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP91 | c.1779G>T p.E593D | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH12 | c.8675C>A p.S2892Y (on ENST00000351747; = p.S3760Y on NM_001366028.2) | Missense Mutation (SNP) | VAF 146/312 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.246); called by muse, mutect2
- FAT3 | c.1225T>A p.Y409N | Missense Mutation (SNP) | VAF 131/275 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GGH | c.88A>C p.T30P | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- GPATCH4 | c.622_623insC p.K208Tfs*19 | Frame Shift Ins (INS) | VAF 48/126 reads (38%) | called by mutect2, pindel*, varscan2
- GPHB5 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC4 | c.166T>A p.Y56N | Missense Mutation (SNP) | VAF 97/405 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LAMB1 | c.2320G>T p.E774* | Nonsense Mutation (SNP) | VAF 35/178 reads (20%) | called by muse, mutect2, varscan2
- LTB | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 141/290 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTN1 | c.1311+2T>C p.X437_splice | Splice Site (SNP) | VAF 56/121 reads (46%) | called by muse, mutect2, varscan2
- NETO1 | c.656T>C p.L219S | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- NKAP | c.938T>A p.L313Q | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSPC1 | c.362T>C p.F121S | Missense Mutation (SNP) | VAF 24/24 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RFTN1 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.204); called by muse, varscan2
- SARS1 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SIRT7 | c.337-3C>T | Splice Region (SNP) | VAF 26/240 reads (11%) | called by muse, mutect2
- SLITRK5 | c.649T>A p.Y217N | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SP140L | c.97A>C p.S33R | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TMEM39B | c.1247G>C p.S416T | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- USP34 | c.6731A>G p.E2244G | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- XRN1 | c.2688T>G p.N896K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZCCHC14 | c.719C>G p.S240C (on ENST00000268616; = p.S377C on NM_015144.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF430 | c.630T>A p.C210* | Nonsense Mutation (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2, varscan2
- ZNF69 | c.510A>C p.K170N | Missense Mutation (SNP) | VAF 36/890 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); called by muse, mutect2
- AP3M1 | c.90T>C p.D30= | Silent (SNP) | VAF 39/379 reads (10%) | called by muse, mutect2
- ARHGEF18 | c.573G>A p.V191= (on ENST00000359920 / NM_001130955.2; = p.V87= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/196 reads (41%) | called by muse, mutect2, varscan2
- EIF2AK1 | c.1716A>G p.P572= | Silent (SNP) | VAF 146/302 reads (48%) | called by muse, mutect2, varscan2
- FARP1 | c.1374G>A p.R458= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.90G>A p.Q30= | Silent (SNP) | VAF 81/140 reads (58%) | catalogued as rs1403247130, COSV100598670; called by muse, mutect2, varscan2
- IGLL5 | c.132A>G p.A44= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs559053132, COSV73250410, COSV73251264; called by muse, varscan2
- MARK1 | c.663C>T p.P221= | Silent (SNP) | VAF 122/307 reads (40%) | catalogued as COSV65067601, COSV65069498; called by muse, mutect2, varscan2
- NRXN2 | c.1407A>T p.A469= | Silent (SNP) | VAF 19/158 reads (12%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.1746C>T p.A582= (on ENST00000379409; = p.A530= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as rs557121401; called by muse, mutect2, varscan2
- PRRC2A | c.4461A>G p.Q1487= | Silent (SNP) | VAF 11/220 reads (5%) | catalogued as rs1203533105; called by muse, mutect2
- RFTN1 | c.213G>A p.E71= | Silent (SNP) | VAF 50/126 reads (40%) | called by muse, varscan2
- SEL1L | c.33G>T p.L11= | Silent (SNP) | VAF 90/181 reads (50%) | called by muse, mutect2, varscan2
- SPARC | c.843C>A p.I281= | Silent (SNP) | VAF 13/211 reads (6%) | called by muse, mutect2
- SYBU | c.612T>A p.L204= (on ENST00000276646 / NM_001099754.2; = p.L203= on NM_017786.6) | Silent (SNP) | VAF 97/183 reads (53%) | called by muse, mutect2, varscan2
- TCF4 | c.1059A>C p.P353= | Silent (SNP) | VAF 55/119 reads (46%) | catalogued as COSV61902948; called by muse, mutect2, varscan2
- TEX43 | c.144T>C p.R48= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs762904159; called by muse, mutect2, varscan2
- AC008080.1 | n.429_430del | RNA (DEL) | VAF 61/186 reads (33%) | called by mutect2, pindel, varscan2
- AC011525.1 | n.1255A>G | RNA (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- AC024651.2 | n.17G>T | RNA (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-1319+932C>T | Intron (SNP) | VAF 66/131 reads (50%) | catalogued as rs1219827580; called by muse, mutect2, varscan2
- AP1G1 | c.326+14T>A | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- AP3D1 | c.2800-51G>T | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- ARMC8 | c.*786A>G | 3'UTR (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- BCHE | c.*414A>T | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- BCL11B | c.*4637del | 3'UTR (DEL) | VAF 37/65 reads (57%) | called by mutect2, varscan2
- CBX5 | c.*8399T>A | 3'UTR (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- CFTRP2 | n.7T>C | RNA (SNP) | VAF 15/63 reads (24%) | catalogued as rs1479371084; called by muse, mutect2, varscan2
- CYB5B | c.*3172A>G | 3'UTR (SNP) | VAF 41/146 reads (28%) | catalogued as rs528332897; called by muse, mutect2, varscan2
- CYBA | c.-16C>G | 5'UTR (SNP) | VAF 26/53 reads (49%) | catalogued as COSV99879842; called by muse, mutect2, varscan2
- DDX21 | c.*1345T>G | 3'UTR (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- DEF8 | chr16:89948726 G>C | 5'Flank (SNP) | VAF 26/44 reads (59%) | called by muse, mutect2, varscan2
- DNAJC30 | c.*429C>A | 3'UTR (SNP) | VAF 37/61 reads (61%) | called by muse, mutect2, varscan2
- EHBP1 | c.-260G>A | 5'UTR (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- EIF4A1 | c.72+95A>G | Intron (SNP) | VAF 60/133 reads (45%) | catalogued as rs1375634007; called by muse, mutect2, varscan2
- ELAPOR2 | c.*1125G>A | 3'UTR (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- ELOVL4 | c.*1449dup | 3'UTR (INS) | VAF 34/76 reads (45%) | catalogued as rs1012946943; called by mutect2, varscan2
- FAM167A | c.381+9147G>A | Intron (SNP) | VAF 55/117 reads (47%) | called by muse, mutect2, varscan2
- FBN1 | c.6998-218C>T | Intron (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- GLIPR1L2 | c.670+30dup | Intron (INS) | VAF 106/258 reads (41%) | catalogued as rs769479789; called by mutect2, varscan2
- GMEB1 | chr1:28715282 T>G | 3'Flank (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- GMPR2 | c.-352G>A | 5'UTR (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- GTF2IRD2 | c.*383A>G | 3'UTR (SNP) | VAF 6/51 reads (12%) | catalogued as rs2529314; called by muse, varscan2
- IFFO2 | c.*2379del | 3'UTR (DEL) | VAF 39/298 reads (13%) | catalogued as rs981124025; called by mutect2, pindel, varscan2
- IL18R1 | c.*115T>A | 3'UTR (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- IL6ST | c.*3242T>G | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- INTS3 | c.*741T>C | 3'UTR (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- IQSEC1 | c.*1568A>G | 3'UTR (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- KIAA0319L | c.*215T>C | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- KIFC3 | c.*500C>T | 3'UTR (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- KLF5 | c.*367C>T | 3'UTR (SNP) | VAF 33/39 reads (85%) | catalogued as rs1566567851; called by muse, mutect2, varscan2
- LARP6 | c.200+1619C>T | Intron (SNP) | VAF 58/113 reads (51%) | called by muse, mutect2, varscan2
- LEFTY2 | chr1:225941306 del TCACACCCCTGGGACCTCCTGGGAGC | 5'Flank (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- LINC00174 | n.3331C>G | RNA (SNP) | VAF 38/93 reads (41%) | catalogued as rs1335635976; called by muse, mutect2, varscan2
- LZTS1 | c.*760A>G | 3'UTR (SNP) | VAF 61/124 reads (49%) | called by muse, mutect2, varscan2
- MAF | c.*854C>A | 3'UTR (SNP) | VAF 46/109 reads (42%) | catalogued as rs1338421346; called by muse, mutect2, varscan2
- MAP3K20 | c.988-3676A>C | Intron (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- MPDZ | c.*9C>A | 3'UTR (SNP) | VAF 43/71 reads (61%) | called by muse, mutect2, varscan2
- MRRFP1 | n.328T>G | RNA (SNP) | VAF 43/123 reads (35%) | called by muse, mutect2, varscan2
- MYO1E | c.-82A>G | 5'UTR (SNP) | VAF 84/152 reads (55%) | called by muse, varscan2
- MYO1E | c.-252A>C | 5'UTR (SNP) | VAF 67/162 reads (41%) | called by muse, mutect2, varscan2
- NAA15 | c.*370A>C | 3'UTR (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- PCLO | c.13300+178T>C | Intron (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- PEX26 | c.-167C>T | 5'UTR (SNP) | VAF 64/139 reads (46%) | catalogued as rs886057244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGM5 | c.1159+1280T>G | Intron (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- PHF12 | c.322-144A>T | Intron (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- PKDREJ | c.*244_*250del | 3'UTR (DEL) | VAF 92/206 reads (45%) | called by mutect2, pindel, varscan2
- RALGAPB | c.*3057A>T | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- ROBO1 | c.173-79564G>T | Intron (SNP) | VAF 103/264 reads (39%) | called by muse, mutect2, varscan2
- RSU1 | c.*1240G>A | 3'UTR (SNP) | VAF 176/288 reads (61%) | catalogued as rs1433764528; called by muse, varscan2
- S1PR2 | c.-43+781G>A | Intron (SNP) | VAF 64/111 reads (58%) | called by muse, varscan2
- SART3 | chr12:108522586 C>A | 3'Flank (SNP) | VAF 42/70 reads (60%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.*1414C>T | 3'UTR (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- SOX5 | c.-47C>T | 5'UTR (SNP) | VAF 109/669 reads (16%) | catalogued as rs756144060; called by muse, mutect2, varscan2
- SPRY3 | c.*6217G>T | 3'UTR (SNP) | VAF 115/294 reads (39%) | called by muse, mutect2, varscan2
- TBL3 | c.*269G>A | 3'UTR (SNP) | VAF 69/136 reads (51%) | called by muse, mutect2, varscan2
- TREML2 | c.*2025G>A | 3'UTR (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- TSHB | c.*59T>A | 3'UTR (SNP) | VAF 27/212 reads (13%) | catalogued as COSV99859049; called by muse, mutect2, varscan2
- TTC3 | c.*1535T>G | 3'UTR (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- ULK2 | c.-327G>A | 5'UTR (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- URM1 | c.188+514G>T | Intron (SNP) | VAF 90/167 reads (54%) | called by muse, mutect2, varscan2
- VANGL1 | chr1:115695114 C>T | 3'Flank (SNP) | VAF 43/101 reads (43%) | called by muse, mutect2, varscan2
- VIL1 | c.*633A>T | 3'UTR (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-2460G>A | Intron (SNP) | VAF 149/311 reads (48%) | called by muse, mutect2, varscan2
- YOD1 | c.*2430T>C | 3'UTR (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
